Gene-level copy-number profile of tumor specimen TCGA-2G-AAKK-01A from TCGA case TCGA-2G-AAKK, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 27.3 years (9,982 days).
Specimen TCGA-2G-AAKK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53496a4e-f39b-4b91-9c8b-05cc1e4620bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAKK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/eb2c5c6b-ef43-411b-8031-0a7ec62b8276

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 29; copy number 2: 23,794; copy number 3: 30,693; copy number 4: 3,002; copy number 5: 25; copy number 6: 42; copy number 7: 819.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 819 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–33,718,217, 819 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
